Somatic mutation profile of tumor specimen TCGA-44-6775-01C (aliquot TCGA-44-6775-01C-02D-A271-08) from TCGA case TCGA-44-6775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.3 years (26,415 days).
Specimen TCGA-44-6775-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6646a893-e711-476f-96f3-461c8045aaf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6775-10A (Blood Derived Normal), aliquot TCGA-44-6775-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd818188-0e89-4961-ac1a-e4e490746d17

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4370G>A p.W1457* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs776770546, COSV61276279, COSV61280573; called by muse, mutect2, varscan2
- AEBP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764745972, COSV56261407; called by muse, mutect2, varscan2
- CDH18 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56936695, COSV56962343; called by muse, mutect2, varscan2
- CLDN11 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.041); catalogued as rs1409189641, COSV50355070; called by muse, mutect2
- CSMD1 | c.2260C>T p.R754C (on ENST00000520002; = p.R753C on NM_033225.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs909617693; called by muse, mutect2
- CSMD3 | c.7704C>A p.Y2568* (on ENST00000297405 / NM_001363185.1; = p.Y2464* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV52134658, COSV52266109; called by muse, mutect2
- CTC1 | c.1373G>T p.W458L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV59852041; called by muse, mutect2
- CWC27 | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759472038, COSV66888888; called by muse, mutect2
- CXCR2 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59282156; called by muse, mutect2, varscan2
- DNAH17 | c.4735C>T p.P1579S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99062302; called by muse, mutect2
- EXPH5 | c.5934C>G p.Y1978* | Nonsense Mutation (SNP) | VAF 8/204 reads (4%) | catalogued as COSV104380371, COSV56208559; called by muse, mutect2
- FBXW9 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100790258; called by muse, mutect2, varscan2
- FDPS | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV52742913; called by muse, mutect2, varscan2
- FOXH1 | c.899G>C p.C300S | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as COSV100023389; called by muse, mutect2
- GABRA2 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV62920160; called by muse, mutect2
- IBSP | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1262583902, COSV56897395; called by muse, mutect2, varscan2
- KAT2B | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55434770; called by muse, mutect2
- KATNAL1 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 62/314 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV66064908; called by muse, mutect2, varscan2
- KLF17 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64857036; called by muse, mutect2, varscan2
- KLHL4 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64143984, COSV64148115; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV59113372; called by muse, mutect2, varscan2
- MIB2 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61757586; called by muse, mutect2
- MRPS5 | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV55535461; called by muse, mutect2
- MYT1 | c.2528+2T>C p.X843_splice | Splice Site (SNP) | VAF 78/261 reads (30%) | catalogued as COSV60513900; called by muse, mutect2, varscan2
- NF1 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as CD1415163, COSV62222291; called by muse, mutect2, varscan2
- OR6C6 | c.516T>G p.I172M | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100626389; called by muse, mutect2
- PCDHB13 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.303); catalogued as COSV53393226; called by muse, mutect2
- PHF20 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148716053; called by mutect2, varscan2
- PTPRN | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1181242319, COSV55352439; called by muse, mutect2, varscan2
- REG3A | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs1048512257, COSV59408975, COSV59410712, COSV59411752; called by muse, mutect2, varscan2
- SAGE1 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV61018235; called by muse, mutect2, varscan2
- SBF2 | c.4099A>G p.T1367A | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1362020336, COSV56311943; called by muse, mutect2, varscan2
- TEC | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs746395396, COSV63354027; called by muse, mutect2
- TEX11 | c.629T>C p.M210T (on ENST00000344304; = p.M195T on NM_031276.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1196396837, COSV60235968; called by muse, mutect2, varscan2
- TNC | c.6098G>T p.R2033L | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV60790736; called by muse, mutect2, varscan2
- UGGT2 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV65079669; called by muse, mutect2, varscan2
- VWA3B | c.3311T>C p.V1104A | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs927356360, COSV69034257; called by muse, mutect2
- YTHDC1 | c.1867T>A p.Y623N (on ENST00000344157 / NM_001031732.4; = p.Y605N on NM_133370.4) | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60012155; called by muse, mutect2
- ZBTB7B | c.746G>A p.G249E (on ENST00000292176; = p.G283E on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.039); catalogued as COSV52694899; called by muse, mutect2, varscan2
- BCL2L13 | c.311T>C p.L104S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- GPR160 | c.940del p.W314Gfs*22 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- MET | c.3020_3028+4delinsG p.X1007_splice | Splice Site (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2*
- MIB1 | c.947T>A p.I316N | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2
- PIK3C2B | c.3803T>C p.I1268T | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- TRPM6 | c.3572A>G p.N1191S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AUP1 | c.693C>T p.R231= | Silent (SNP) | VAF 21/210 reads (10%) | catalogued as COSV51214379; called by muse, mutect2, varscan2
- FBXO4 | c.693C>T p.F231= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV55854301; called by muse, mutect2, varscan2
- KCNA4 | c.1350A>G p.R450= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV60256061; called by muse, mutect2
- KRTAP3-2 | c.141C>T p.C47= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV101195993; called by muse, mutect2, varscan2
- PAM | c.513T>A p.I171= | Silent (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- RBM15 | c.720C>T p.L240= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as COSV63924504; called by muse, mutect2
- RFC1 | c.3180A>G p.A1060= (on ENST00000381897 / NM_001363496.2; = p.A1059= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV56470330; called by muse, mutect2, varscan2
- TBL2 | c.837C>A p.S279= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV59788399; called by muse, mutect2, varscan2
- TTLL3 | c.1179C>A p.L393= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100047064, COSV59615907; called by muse, mutect2, varscan2
- VBP1 | c.375G>A p.L125= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV99660659; called by muse, mutect2, varscan2
- ZMYM5 | c.1023T>C p.C341= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV61990061; called by muse, mutect2, varscan2
- AC074085.2 | n.341C>A | RNA (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
